Somatic mutation profile of tumor specimen TCGA-WB-A814-01A (aliquot TCGA-WB-A814-01A-11D-A35I-08) from TCGA case TCGA-WB-A814, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, malignant; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 35.4 years (12,936 days).
Specimen TCGA-WB-A814-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b8d48ab-9bf7-4a0f-a3de-239ba2dfd9a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A814-10A (Blood Derived Normal), aliquot TCGA-WB-A814-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9923726-dab7-4da5-9986-ee424e5239b9

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.13468G>A p.G4490R | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1215915217; called by muse, mutect2, varscan2
- ALMS1 | c.8542G>A p.G2848S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.079); catalogued as COSV52507329; called by muse, mutect2, varscan2
- EPAS1 | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1513699, COSV55383943, COSV55387430; called by muse, mutect2, varscan2
- FEZ1 | c.676C>A p.H226N | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.059); catalogued as COSV54029796; called by muse, mutect2
- RNF168 | c.881T>C p.I294T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1221255422; called by muse, mutect2, varscan2
- TGFBR3 | c.2227C>T p.Q743* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV53022699; called by muse, mutect2, varscan2
- EMC1 | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
